Gene-level copy-number profile of tumor specimen TCGA-D3-A1Q9-06A from TCGA case TCGA-D3-A1Q9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.2 years (26,746 days).
Specimen TCGA-D3-A1Q9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ade66548-6898-4863-900d-7eaabf8919cb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A1Q9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53d95ad6-f856-4090-b4d3-f1dc92deace0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,201; copy number 2: 12,987; copy number 3: 17,607; copy number 4: 25,117; copy number 5: 828; copy number 6: 590; copy number 7: 414; copy number 8: 407; copy number 9: 302; copy number 10: 199; copy number 11: 15; copy number 12: 41; copy number 13: 7; copy number 19: 8; copy number 20: 50; copy number 29: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A1Q9-06A-11D-A192-01): tumor purity 0.69, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr11:80,957,317–81,431,520, 3 genes (within-gene range 0–2): AP003398.1, AP003398.2, AP003464.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 661 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes, copy number 9: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr3:67,654,669–72,861,914, 64 genes, copy number 10–19 (within-gene range 8–19) (broad region; genes not listed).
- chr3:75,906,695–77,649,964, 1 gene, copy number 11 (within-gene range 7–11): ROBO2.
- chr3:77,092,057–80,789,388, 22 genes, copy number 9–13: RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050.
- chr5:470,456–524,449, 1 gene, copy number 10 (within-gene range 6–10): SLC9A3.
- chr5:524,109–1,309,377, 27 genes, copy number 10: AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr5:8,387,638–8,457,564, 1 gene, copy number 12 (within-gene range 7–12): AC091965.1.
- chr5:8,444,949–9,546,075, 23 genes, copy number 12 (within-gene range 1–12): AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1.
- chr11:64,270,062–64,723,197, 23 genes, copy number 10 (within-gene range 2–10): GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155, RPS6KA4, MIR1237, LINC02723, AP003774.1, LINC02724, AP005273.2, AP005273.1, AP006288.1, SLC22A11, SLC22A12, NRXN2, NRXN2-AS1.
- chr11:69,072,915–69,162,440, 1 gene, copy number 9 (within-gene range 7–9): AP003071.5.
- chr11:69,147,228–70,075,469, 24 genes, copy number 9: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P.
- chr12:66,767–1,495,933, 27 genes, copy number 10 (within-gene range 5–10): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1.
- chr18:47,390–3,478,978, 85 genes, copy number 20–29 (broad region; genes not listed).
- chr18:3,571,215–3,608,336, 4 genes, copy number 20: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2.
- chr18:11,326,270–11,929,476, 25 genes, copy number 9: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3.
- chr18:33,578,219–34,226,429, 6 genes, copy number 9 (within-gene range 7–9): ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2.
- chr18:42,743,227–43,499,836, 4 genes, copy number 9: RIT2, AC100779.1, SYT4, AC022743.1.
- chr20:28,563,850–35,147,336, 179 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:35,752,814–42,063,969, 138 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
